Somatic mutation profile of tumor specimen TARGET-10-PARTGB-09A (aliquot TARGET-10-PARTGB-09A-01D) from TARGET case TARGET-10-PARTGB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.6 years (6,782 days).
Specimen TARGET-10-PARTGB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db45bab4-9ddc-4acf-9130-189642af4630.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARTGB-14A (Bone Marrow Normal), aliquot TARGET-10-PARTGB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89616ee3-e322-437a-b053-03cc08151fd3

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 1 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Intron 3, 5'UTR 3, 5'Flank 1, Frame Shift Ins 1, Silent 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- JAK2 | c.2047A>G p.R683G | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519721, COSV67572554, COSV67587550; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KIF1A | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs672601368, CM150187, CM157166, COSV57482056; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD24 | c.3238G>A p.A1080T | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as rs376946018, COSV99517486; called by muse, mutect2, varscan2
- DNAH5 | c.10229C>T p.T3410M | Missense Mutation (SNP) | VAF 120/259 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs186180802; called by muse, mutect2, varscan2
- DOT1L | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67110810; called by muse, mutect2
- EBF1 | c.713C>A p.S238Y | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58175281; called by muse, mutect2
- IKZF1 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 63/94 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs768183030; called by muse, mutect2, varscan2
- REV1 | c.2621G>A p.R874Q | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0.041); catalogued as rs550221075; called by muse, mutect2, varscan2
- SETD2 | c.3918G>A p.W1306* | Nonsense Mutation (SNP) | VAF 54/180 reads (30%) | catalogued as COSV57443460; called by muse, mutect2, varscan2
- TRIM32 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs866695848; called by muse, mutect2, varscan2
- ZNF878 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs539241283, COSV72155903, COSV72155976; called by muse, mutect2, varscan2
- IGSF11 | c.59C>A p.A20E (on ENST00000393775 / NM_001015887.3; = p.A19E on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- JAK2 | c.2651T>C p.L884P | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH7 | c.2546G>A p.R849K | Missense Mutation (SNP) | VAF 55/160 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PEBP4 | c.461T>G p.V154G | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- PTPN18 | c.858_859insCC p.T287Pfs*107 | Frame Shift Ins (INS) | VAF 85/219 reads (39%) | called by mutect2, pindel, varscan2
- UNC93A | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DYNC1I2 | c.876G>A p.P292= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as rs752311418; called by muse, mutect2, varscan2
- LHX1 | c.-236G>A | 5'UTR (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2, varscan2
- MECOM | c.-54-74A>G | Intron (SNP) | VAF 5/13 reads (38%) | catalogued as rs1342081835; called by muse, mutect2
- POLN | c.*189G>A | 3'UTR (SNP) | VAF 34/75 reads (45%) | catalogued as rs1010800041; called by muse, mutect2, varscan2
- PPP2R2A | c.347-1174T>C | Intron (SNP) | VAF 101/232 reads (44%) | catalogued as rs762495696, COSV100277159; called by muse, mutect2, varscan2
- PRKN | c.-53C>T | 5'UTR (SNP) | VAF 4/32 reads (13%) | catalogued as rs762055309; called by mutect2, varscan2
- S100A5 | chr1:153541468 G>C | 5'Flank (SNP) | VAF 8/73 reads (11%) | catalogued as rs1288066587; called by muse, mutect2, varscan2
- SGK1 | c.285+169T>C | Intron (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- SRP19 | c.-70_-69del | 5'UTR (DEL) | VAF 34/88 reads (39%) | called by pindel, varscan2
